Gene-level copy-number profile of tumor specimen TCGA-UD-AAC5-01A from TCGA case TCGA-UD-AAC5, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.6 years (24,314 days).
Specimen TCGA-UD-AAC5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.6a732496-2345-46c7-8cce-cecc96a15271.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UD-AAC5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e14bad6d-159c-4fd8-934a-d813547cfe90

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 143; copy number 1: 2,746; copy number 2: 10,837; copy number 3: 29,320; copy number 4: 13,335; copy number 5: 381; copy number 6: 2,313; copy number 7: 737.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UD-AAC5-01A-11D-A39Q-01): tumor purity 0.66, ploidy 3.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 143 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,883,046–118,989,556, 1 gene (within-gene range 0–2): TBX15.
- chr4:162,022,733–162,047,567, 1 gene: AC023136.1.
- chr9:20,341,669–31,645,160, 141 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 737 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:53,708,517–91,906,187, 735 genes, copy number 7 (broad region; genes not listed).
- chr12:92,008,052–92,032,392, 2 genes, copy number 7: AC123512.1, AC025164.2.

Autosomal genes at a single copy (total copy number 1): 325. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
